HCMI case HCM-CSHL-0377-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d58136f6-2e90-40b4-b7fb-3478011efa00

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1948; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Hepatic flexure of colon; Classification of tumor: primary; Age at diagnosis: 69.7 years (25,463 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIA; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 53 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 145 days; Disease response: Stable Disease; Progression or recurrence: No.

Molecular and laboratory tests
- MLH1 (IHC): Positive.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Positive.
- Test (IHC): Positive; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 69.4 kg; Height: 177.8 cm; BMI: 22.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0377-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0377-C18-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 6; Percent necrosis: 1; Percent stromal cells: 18; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 6.
  Slide HCM-CSHL-0377-C18-01A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 18; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 6.
- Sample HCM-CSHL-0377-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0377-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
